Somatic mutation profile of tumor specimen C3N-02266-01 (aliquot CPT0188950006) from CPTAC case C3N-02266, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 56.2 years (20,536 days).
Specimen C3N-02266-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99868305-6adb-433c-8a6b-28e3eb927fe7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02266-31 (Blood Derived Normal), aliquot CPT0188970002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/722fdb5a-7e66-4ae2-bae0-36b6346e8926

The open-access MAF lists 31 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Intron 5, Silent 5, 5'Flank 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.6644C>T p.S2215F | Missense Mutation (SNP) | VAF 8/106 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, mutect2
- VHL | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 20/410 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1559429613, CM941380, COSV56544074, COSV56552085; ClinVar: pathogenic; called by muse, mutect2
- COL15A1 | c.2124G>C p.K708N | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV100897817; called by muse, mutect2
- DENND3 | c.1381C>T p.H461Y | Missense Mutation (SNP) | VAF 11/313 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV52801954; called by muse, mutect2
- DMD | c.5154+2T>A p.X1718_splice | Splice Site (SNP) | VAF 10/126 reads (8%) | catalogued as CS013452, CS073465; called by muse, mutect2
- FBXO31 | c.937G>A p.G313S | Missense Mutation (SNP) | VAF 21/392 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1407640986; called by muse, mutect2
- MAGEA12 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.971); catalogued as COSV63295564; called by muse, mutect2, varscan2
- ABLIM1 | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2
- CDH1 | c.802A>C p.K268Q | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- CENPF | c.1286A>G p.K429R | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.22); called by muse, mutect2
- FCRLB | c.582C>G p.F194L | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2
- GAS6 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.059); called by muse, mutect2
- HMX2 | c.65T>C p.I22T | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- KRT85 | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- MACF1 | c.14095G>A p.D4699N (on ENST00000372915; = p.D2632N on NM_012090.5) | Missense Mutation (SNP) | VAF 16/288 reads (6%) | called by muse, mutect2
- PGLYRP2 | c.1462G>T p.A488S | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.262); called by muse, mutect2
- RHOBTB2 | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 17/221 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC4A4 | c.934G>T p.G312C (on ENST00000264485 / NM_001098484.3; = p.G268C on NM_003759.4) | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF256 | c.1249A>C p.T417P | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.223); called by muse, mutect2
- ATG16L1 | c.1818G>A p.Q606= (on ENST00000392017 / NM_030803.7; = p.Q587= on NM_017974.4) | Silent (SNP) | VAF 16/223 reads (7%) | called by muse, mutect2
- EPHA5 | c.1368G>A p.Q456= | Silent (SNP) | VAF 7/110 reads (6%) | catalogued as COSV56683933; called by muse, mutect2
- GPT | c.615T>C p.D205= | Silent (SNP) | VAF 20/526 reads (4%) | called by muse, mutect2
- RANBP2 | c.3042A>C p.G1014= | Silent (SNP) | VAF 18/372 reads (5%) | called by muse, mutect2
- SLC45A1 | c.306C>T p.A102= | Silent (SNP) | VAF 15/254 reads (6%) | called by muse, mutect2
- DOCK11 | c.3292+501A>T | Intron (SNP) | VAF 6/89 reads (7%) | called by muse, mutect2
- GP6 | c.35-35A>T | Intron (SNP) | VAF 20/404 reads (5%) | called by muse, mutect2
- GP6 | c.35-36G>T | Intron (SNP) | VAF 20/402 reads (5%) | called by muse, mutect2
- MTFR1L | chr1:25820610 C>G | 5'Flank (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- RNF207 | c.324+133C>G | Intron (SNP) | VAF 9/180 reads (5%) | called by muse, mutect2
- SLC6A19 | c.-36C>T | 5'UTR (SNP) | VAF 18/400 reads (5%) | catalogued as rs111886371; called by muse, mutect2
- THRA | c.1110+33del | Intron (DEL) | VAF 64/467 reads (14%) | called by mutect2, pindel, varscan2
